Somatic mutation profile of tumor specimen MP2PRT-PASMCE-TMP1-A (aliquot MP2PRT-PASMCE-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASMCE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,090 days).
Specimen MP2PRT-PASMCE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b49b3fb0-b767-4aa0-b249-83c6687239b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASMCE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASMCE-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/231bd574-d89a-4e08-ac9f-92c92fadb29c

The open-access MAF lists 24 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.2134C>T p.R712* (on ENST00000303395 / NM_001202435.3; = p.R701* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 113/333 reads (34%) | catalogued as rs794726730, CM024300, CX096176, COSV57668399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BHMG1 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 133/685 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs527392009, COSV58222684; called by muse, mutect2, varscan2
- DYNC1H1 | c.11548A>G p.T3850A | Missense Mutation (SNP) | VAF 51/470 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV64135474; called by muse, mutect2, varscan2
- FJX1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 56/786 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58553131; called by muse, mutect2
- GNAL | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 91/509 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750928118; called by muse, mutect2, varscan2
- NKD2 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 181/787 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376974391; called by muse, mutect2, varscan2
- OR52N4 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 93/495 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs765711389, COSV57893602; called by muse, mutect2, varscan2
- PRTG | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as rs200918046; called by muse, mutect2
- RFX7 | c.3322C>T p.H1108Y (on ENST00000559447 / NM_001368074.1; = p.H1205Y on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/514 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1180454650; called by muse, mutect2
- SPINK6 | c.46T>C p.C16R | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV100347117; called by muse, varscan2
- TMEM74 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 99/494 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755393829, COSV52462669; called by muse, mutect2, varscan2
- BCORL1 | c.2377G>T p.G793W | Missense Mutation (SNP) | VAF 22/444 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCORL1 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CHD6 | c.3120G>A p.K1040= | Splice Region (SNP) | VAF 59/186 reads (32%) | called by muse, mutect2, varscan2
- GMCL1 | c.1307T>C p.L436P | Missense Mutation (SNP) | VAF 33/656 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); called by muse, mutect2
- IGHV3-66 | c.339_344delinsGG p.Y113* | Nonsense Mutation (DEL) | VAF 19/61 reads (31%) | called by pindel, varscan2*
- MSL2 | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- RENBP | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 152/328 reads (46%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC22A16 | c.1715A>G p.D572G | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- TMC3 | c.389T>A p.I130N | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF597 | c.17dup p.T7Dfs*11 | Frame Shift Ins (INS) | VAF 131/623 reads (21%) | called by mutect2, pindel, varscan2
- ADCY1 | c.2283G>A p.T761= | Silent (SNP) | VAF 108/428 reads (25%) | catalogued as rs746675248, COSV52030091; called by muse, mutect2, varscan2
- LRRC58 | c.1089C>G p.R363= | Silent (SNP) | VAF 74/315 reads (23%) | called by muse, mutect2, varscan2
- NYAP2 | c.690G>A p.Q230= | Silent (SNP) | VAF 43/732 reads (6%) | catalogued as rs1208554528; called by muse, mutect2
